Somatic mutation profile of tumor specimen TARGET-40-NAAGJK-01A (aliquot TARGET-40-NAAGJK-01A-01D) from TARGET case TARGET-40-NAAGJK, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.3 years (5,595 days).
Specimen TARGET-40-NAAGJK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4463ce3a-f447-432a-8784-039f207fb94c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJK-10B (Blood Derived Normal), aliquot TARGET-40-NAAGJK-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f6f5342-595f-4072-9e01-57e80be69e7a

The open-access MAF lists 24 somatic variants for this specimen: 10 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 9, Missense Mutation 8, Intron 4, Frame Shift Del 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CERT1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1437972108; called by muse, mutect2, varscan2
- GPALPP1 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1035030446; called by muse, mutect2, varscan2
- TTLL7 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs769393930, COSV53081636; called by muse, mutect2, varscan2
- APOB | c.4370C>T p.A1457V | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PHC3 | c.2301del p.D768Tfs*2 (on ENST00000494943 / NM_001308116.2; = p.D780Tfs*2 on NM_024947.4) | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | called by mutect2, varscan2
- SPAG5 | c.2581G>C p.E861Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SUPT6H | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.267); called by muse, varscan2
- SUPT6H | c.3315_3326del p.D1105_A1108del | In Frame Del (DEL) | VAF 34/97 reads (35%) | called by pindel, varscan2
- TCF12 | c.1256T>A p.V419E | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMEM132D | c.895G>C p.V299L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ALOX12B | c.1311C>T p.I437= | Silent (SNP) | VAF 73/328 reads (22%) | catalogued as rs1384613481; called by muse, varscan2
- ATAD3A | c.351C>T p.A117= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs2478791; called by muse, varscan2
- KCNB1 | c.1005C>A p.I335= | Silent (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- OR4N2 | c.592C>T p.L198= | Silent (SNP) | VAF 134/296 reads (45%) | called by muse, mutect2, varscan2
- SDK1 | c.3537C>T p.S1179= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs200756610; called by muse, mutect2, varscan2
- SPEF1 | c.57C>T p.N19= | Silent (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- SUPT6H | c.3333G>A p.L1111= | Silent (SNP) | VAF 37/85 reads (44%) | called by muse, varscan2
- UMODL1 | c.2775C>T p.C925= (on ENST00000408910 / NM_001004416.2; = p.C1053= on NM_173568.3) | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs201946845, COSV101252786; called by muse, mutect2, varscan2
- ZBTB12 | c.91C>A p.R31= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs145104876; called by muse, mutect2, varscan2
- CACNB4 | c.699+208C>A | Intron (SNP) | VAF 18/350 reads (5%) | called by muse, mutect2
- GRB10 | c.1389+51C>A | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- KCNQ1 | c.387-6368T>C | Intron (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- NPDC1 | c.113-331G>C | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as COSV61910980; called by muse, mutect2
- Y_RNA | chr7:23490806 T>A | 3'Flank (SNP) | VAF 56/111 reads (50%) | called by muse, mutect2, varscan2
